FM case AD15029 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/ba9a3401-a25e-45e5-ae77-f47a90e05a75

Female, 54.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the skin. Sample type: Tumor.
